Somatic mutation profile of tumor specimen TCGA-CE-A3ME-01A (aliquot TCGA-CE-A3ME-01A-11D-A20C-08) from TCGA case TCGA-CE-A3ME, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 51.2 years (18,714 days).
Specimen TCGA-CE-A3ME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f5f1711-0024-4ce3-8d6e-1ad52661fbd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CE-A3ME-10A (Blood Derived Normal), aliquot TCGA-CE-A3ME-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68014250-d5c4-406c-b649-796ae110dffe

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABR | c.377C>A p.T126N (on ENST00000302538 / NM_021962.5; = p.T89N on NM_001092.5) | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52144746; called by muse, mutect2
- MED1 | c.4495A>T p.K1499* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV56124264; called by mutect2, varscan2
- MYH8 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs754371915, COSV67963621; called by muse, mutect2, varscan2
- COPB1 | c.57A>G p.E19= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV51447924; called by muse, mutect2, varscan2
- PDHA2 | c.399C>T p.L133= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs766615895, COSV54777843, COSV54778645; called by muse, mutect2, varscan2
